Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6881, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6881-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – rectum and sigmoid colon**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the rectosigmoid junction. H.pat: Adenocarcinoma G2.**

Examination performed on:

Macroscopic description:

A 23.6 cm length of large intestine with mesorectum fat tissue of 3 cm in thickness. Cauliflower-shaped tumour sized 5.3 x 4.9 x 10.0 cm found in the mucosa. The lesion surrounds 15% of the intestine circumference, removed by 13.9 cm from the proximal incision line and 3.8 cm from the distal line. Minimal mesorectum margin is 1.5 cm.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Infiltratio carcinomatosa profunda telae adiposae mesorecti. Incision lines free of neoplastic lesions. Metastases carcinomaatopsae in lymphonodo (NoI/XVI). Infiltratio carcinomatosa capsulae lymphonodi.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare recti. Tubulopapillar adenocarcinoma of the rectum.

Metastases carcinomatosa in lymphonodo regionalio. Cancer metastases in regional lymph nodes (No I/XVIII). (G2;)).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 76ae7817-7217-4e42-917e-dbf844d80805 (TCGA-EI-6881.30AA2E3C-207D-4A50-BA74-90A4EC99D085.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).